Gene-level copy-number profile of specimen HCM-BROD-0702-C43-85M from HCMI case HCM-BROD-0702-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 69.3 years (25,295 days).
Specimen HCM-BROD-0702-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 14.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1f6586c3-7af5-4a6d-ba45-2d4fefaf5be3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0702-C43-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/4dd06041-72b5-4780-9a66-f7513930bff6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 457; copy number 1: 1,705; copy number 2: 25,850; copy number 3: 28,930; copy number 4: 1,271; copy number 5: 108; copy number 6: 273; copy number 7: 310.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 310 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:34,593,329–40,122,168, 310 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,024. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
